Somatic mutation profile of tumor specimen TCGA-D6-A4Z9-01A (aliquot TCGA-D6-A4Z9-01A-11D-A25D-08) from TCGA case TCGA-D6-A4Z9, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.3 years (21,659 days).
Specimen TCGA-D6-A4Z9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04c3f256-cf4a-4275-853e-3f9482d1004b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-A4Z9-10A (Blood Derived Normal), aliquot TCGA-D6-A4Z9-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4da3abc2-104c-4c07-a023-6dd15d244c42

The open-access MAF lists 97 somatic variants for this specimen: 72 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 24, Nonsense Mutation 2, Frame Shift Del 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF2 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as rs1555993345, CM950856, COSV58519797; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 32/58 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.2482C>G p.Q828E | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV53978920, COSV99684085; called by muse, mutect2, varscan2
- ARF6 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100028327; called by muse, mutect2, varscan2
- ASPRV1 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100208350; called by muse, mutect2, varscan2
- ASZ1 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.638); catalogued as rs777726233, COSV52912406; called by muse, mutect2, varscan2
- BAG4 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV99781680; called by muse, mutect2, varscan2
- BEND2 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.434); catalogued as COSV101191695, COSV66215427; called by muse, mutect2
- BOD1L1 | c.7898C>A p.P2633H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV99240142; called by muse, mutect2
- BTBD3 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.203); catalogued as COSV54778138, COSV54780790, COSV99655568; called by muse, mutect2, varscan2
- CABS1 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV99908894; called by muse, mutect2, varscan2
- CACNA1C | c.3391G>T p.D1131Y | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100214331; called by muse, mutect2, varscan2
- CARD11 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100829062; called by muse, mutect2, varscan2
- CCDC88C | c.3850A>G p.T1284A | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV101104988; called by mutect2, varscan2
- CCN2 | c.851G>T p.C284F | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100915267; called by muse, mutect2, varscan2
- CDH17 | c.673A>C p.S225R | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99216795; called by muse, mutect2, varscan2
- CERS2 | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99643462; called by muse, mutect2, varscan2
- CHAD | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV99366005; called by muse, mutect2, varscan2
- DCUN1D3 | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs149680095; called by muse, mutect2, varscan2
- DNAH7 | c.5437G>A p.V1813I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV100413422, COSV56777764; called by muse, mutect2, varscan2
- DZIP1L | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs545888037, COSV59522808; called by muse, mutect2, varscan2
- ERBB3 | c.2287A>T p.I763F | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as COSV99915457; called by muse, mutect2, varscan2
- ERV3-1 | c.771C>G p.F257L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.041); catalogued as COSV99275082; called by muse, mutect2, varscan2
- FAT1 | c.7280A>G p.Y2427C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs372188939; called by muse, mutect2, varscan2
- FCN3 | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99585134; called by muse, mutect2, varscan2
- FMO4 | c.1118T>G p.L373R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV100882017; called by muse, mutect2, varscan2
- FREM1 | c.2459C>G p.P820R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101083577; called by muse, mutect2, varscan2
- GDF6 | c.1014C>A p.F338L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1474559057, COSV99747493; called by muse, mutect2, varscan2
- GLCCI1 | c.1088A>G p.H363R | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.852); catalogued as rs148958007; called by muse, mutect2, varscan2
- GLDN | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); catalogued as rs755994761, COSV100117410; called by muse, mutect2
- GLRB | c.407A>C p.K136T | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.324); catalogued as COSV100029368; called by muse, mutect2, varscan2
- GOLGA3 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs561773900, COSV99201836; called by muse, mutect2, varscan2
- GRM8 | c.604C>G p.Q202E | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs995067862, COSV100279652; called by muse, mutect2, varscan2
- GRM8 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100279655; called by muse, mutect2, varscan2
- HNRNPR | c.1769A>T p.N590I | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.278); catalogued as COSV100164244; called by muse, mutect2, varscan2
- ICE1 | c.4963T>C p.S1655P | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as rs370382183; called by muse, mutect2, varscan2
- KCTD19 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs190821373; called by muse, mutect2, varscan2
- KIF25 | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100596223; called by muse, mutect2, varscan2
- KMT2E | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.824); catalogued as COSV99995644; called by muse, mutect2, varscan2
- KMT2E | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.523); catalogued as rs754778765, COSV99995646; called by muse, mutect2, varscan2
- LEPR | c.2616G>A p.W872* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100756184; called by muse, mutect2, varscan2
- MCM8 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs775072567, COSV54511052; called by muse, mutect2, varscan2
- MICAL1 | c.1439G>T p.R480L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV100668374; called by muse, mutect2, varscan2
- MROH5 | c.1993A>T p.M665L | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101435822; called by muse, mutect2, varscan2
- NEU2 | c.316C>A p.P106T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.088); catalogued as COSV52093654, COSV99290406; called by muse, mutect2, varscan2
- NRG3 | c.607A>T p.S203C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.299); catalogued as COSV100930352; called by muse, mutect2, varscan2
- OR10H3 | c.775C>G p.L259V | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100008273, COSV100008567; called by muse, mutect2, varscan2
- PCLO | c.2675C>G p.P892R | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.165); catalogued as rs750549471, COSV100426375; called by muse, mutect2, varscan2
- PIWIL4 | c.1360A>C p.I454L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as COSV100133018, COSV54412562; called by muse, mutect2, varscan2
- RBM14 | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as rs748136584, COSV100036483; called by muse, mutect2, varscan2
- RNF130 | c.841C>G p.P281A | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99992435; called by muse, mutect2, varscan2
- SALL3 | c.3550C>G p.L1184V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101609905; called by muse, mutect2, varscan2
- SCGB1D4 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.687); catalogued as COSV100669543, COSV62204104; called by muse, mutect2, varscan2
- SDK1 | c.2858C>T p.T953I | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV101268608; called by muse, mutect2, varscan2
- SLC26A9 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs753275770, COSV61604182; called by muse, mutect2, varscan2
- SLC6A2 | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99573155; called by muse, mutect2, varscan2
- SPG11 | c.4941G>T p.Q1647H | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV99967858, COSV99969334; called by muse, mutect2, varscan2
- SPTA1 | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.962); catalogued as rs1486397669, COSV100934047; called by muse, mutect2, varscan2
- SPTBN2 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773857389, COSV100017961; called by muse, mutect2, varscan2
- SRCAP | c.6544C>G p.Q2182E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99348950; called by muse, mutect2, varscan2
- TECRL | c.145A>T p.T49S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV101168230; called by muse, mutect2, varscan2
- TRHDE | c.998C>G p.A333G | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV53872167, COSV99668550; called by muse, mutect2, varscan2
- USH2A | c.3658G>T p.V1220L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.047); catalogued as COSV100227773; called by muse, mutect2, varscan2
- VIPAS39 | c.459T>A p.N153K | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.053); catalogued as COSV100492801; called by muse, mutect2, varscan2
- ZFHX4 | c.2195A>T p.N732I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99254666; called by muse, mutect2, varscan2
- ZNF189 | c.1628A>T p.D543V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV99407047; called by muse, mutect2, varscan2
- ZNF235 | c.770A>G p.H257R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV99349180; called by muse, mutect2, varscan2
- ZNF540 | c.1952A>G p.Y651C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100329405; called by muse, mutect2, varscan2
- CKS1B | c.197dup p.L68Afs*50 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- GON4L | c.3627_3630del p.G1210Ifs*3 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | called by mutect2, pindel, varscan2
- PCLO | c.8795del p.L2932* | Frame Shift Del (DEL) | VAF 22/112 reads (20%) | called by mutect2, varscan2
- SSX2 | c.486T>A p.H162Q (on ENST00000337502 / NM_175698.2; = p.M211K on NM_003147.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- BCL11A | c.1281C>T p.S427= (on ENST00000335712 / NM_001365609.1; = p.S461= on NM_018014.4) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100184582; called by muse, mutect2, varscan2
- CACNA1C | c.3723C>T p.Y1241= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs377686760; ClinVar: likely benign; called by muse, mutect2, varscan2
- CENPF | c.4431A>G p.S1477= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100871424; called by muse, mutect2, varscan2
- CFAP47 | c.567A>T p.P189= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs1393344449, COSV99934102; called by muse, mutect2, varscan2
- CPSF2 | c.954C>G p.A318= | Silent (SNP) | VAF 41/71 reads (58%) | catalogued as COSV100102417; called by muse, mutect2, varscan2
- CPT1A | c.1029C>T p.F343= | Silent (SNP) | VAF 15/409 reads (4%) | catalogued as COSV99680458; called by muse, mutect2
- DNTTIP1 | c.894C>T p.V298= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV99708446; called by muse, mutect2, varscan2
- GTPBP4 | c.1332A>T p.P444= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV100672334; called by muse, mutect2, varscan2
- HMCN1 | c.10209T>C p.A3403= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99622670; called by muse, mutect2, varscan2
- IGHV7-81 | c.57C>A p.S19= | Silent (SNP) | VAF 23/134 reads (17%) | called by muse, mutect2, varscan2
- IGSF1 | c.1926G>A p.R642= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV100811760; called by muse, mutect2, varscan2
- LHX4 | c.12T>C p.S4= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99761076; called by muse, mutect2, varscan2
- LRP1 | c.5061C>A p.A1687= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as COSV99673952; called by muse, mutect2, varscan2
- MYO1B | c.2979G>A p.V993= (on ENST00000304164; = p.V935= on NM_012223.5) | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as rs1451374320, COSV100268417; called by muse, mutect2, varscan2
- OGG1 | c.360C>T p.F120= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV100115018; called by muse, mutect2, varscan2
- OLFM3 | c.294G>A p.Q98= (on ENST00000338858 / NM_001288821.1; = p.Q78= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs1441646468, COSV100128732; called by muse, mutect2, varscan2
- PNLIP | c.519C>T p.H173= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs150321250; called by muse, mutect2, varscan2
- PPP1R8 | c.780C>T p.S260= (on ENST00000311772 / NM_014110.5; = p.S36= on NM_002713.4) | Silent (SNP) | VAF 48/248 reads (19%) | catalogued as rs771406720, COSV99360797; called by muse, mutect2, varscan2
- REXO1 | c.2379C>T p.H793= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as COSV99401951; called by muse, mutect2, varscan2
- RSBN1 | c.2274A>T p.S758= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as rs765637311, COSV99792723; called by muse, mutect2, varscan2
- SNX25 | c.1833G>C p.L611= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV99252190; called by muse, mutect2, varscan2
- UGT2B28 | c.1059G>T p.L353= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV100158502; called by muse, mutect2, varscan2
- ZNF648 | c.504C>A p.P168= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100374364; called by muse, mutect2, varscan2
- ZNFX1 | c.1713A>T p.L571= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as COSV100870707; called by muse, mutect2, varscan2
- GNG11 | c.*2T>C | 3'UTR (SNP) | VAF 18/71 reads (25%) | catalogued as COSV99949298; called by muse, mutect2, varscan2
